Somatic mutation profile of tumor specimen TCGA-13-1497-01A (aliquot TCGA-13-1497-01A-01W-0549-09) from TCGA case TCGA-13-1497, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.0 years (17,528 days).
Specimen TCGA-13-1497-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21553387-c6e0-47fc-9800-f86ba35b72b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1497-10A (Blood Derived Normal), aliquot TCGA-13-1497-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b9b3c39-95dd-4059-aa3f-f64bd8df5940

The open-access MAF lists 169 somatic variants for this specimen: 132 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 34, Frame Shift Del 7, Nonsense Mutation 7, Splice Site 5, Intron 3, Splice Region 2, Translation Start Site 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3BP | c.1476C>A p.S492R | Missense Mutation (SNP) | VAF 146/401 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52554203; called by muse, mutect2, varscan2
- ACLY | c.129G>C p.L43F | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV61253527; called by muse, mutect2, varscan2
- ACTN2 | c.1220G>T p.R407M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV63978779; called by muse, mutect2, varscan2
- ADHFE1 | c.1161G>T p.L387= | Splice Region (SNP) | VAF 12/228 reads (5%) | catalogued as COSV99397541; called by muse, mutect2
- AFF3 | c.3274G>C p.D1092H | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57878319; called by muse, mutect2, varscan2
- ALDH3A2 | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0.027); catalogued as COSV51569285; called by muse, mutect2, varscan2
- ALG2 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.411); catalogued as COSV53061140; called by muse, mutect2, varscan2
- ANGPT1 | c.576-1G>A p.X192_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV52430396, COSV52459986; called by muse, mutect2, varscan2
- ANK2 | c.6124G>T p.A2042S | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV99999325; called by muse, mutect2
- ANKRD35 | c.1964A>T p.E655V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV62911853; called by muse, mutect2, varscan2
- ARSI | c.1600G>T p.G534W | Missense Mutation (SNP) | VAF 64/73 reads (88%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV60818684; called by muse, mutect2, varscan2
- ASS1 | c.1235A>C p.K412T | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as COSV61691047; called by muse, mutect2, varscan2
- ATAD5 | c.3822G>C p.Q1274H | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV58980104; called by muse, mutect2, varscan2
- ATP2B4 | c.1005G>C p.E335D | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV100397276, COSV58185294; called by muse, mutect2, varscan2
- BBS2 | c.2012A>G p.N671S | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV55329242; called by muse, mutect2, varscan2
- C16orf92 | c.330G>T p.L110F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99662263; called by muse, mutect2, varscan2
- CACNA1A | c.1790G>T p.W597L | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64214756; called by muse, mutect2, varscan2
- CASR | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1276839362, CM0910767, COSV56137814, COSV56142229; called by muse, mutect2, varscan2
- CCDC57 | c.861G>C p.E287D | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV58937722; called by muse, mutect2, varscan2
- CLEC14A | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60564649; called by muse, mutect2, varscan2
- CMYA5 | c.7775C>T p.T2592I | Missense Mutation (SNP) | VAF 98/146 reads (67%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.012); catalogued as rs905453308, COSV71410353; called by muse, mutect2, varscan2
- CNTRL | c.1850T>C p.V617A | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV99440968; called by muse, mutect2
- COL14A1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99917819; called by muse, mutect2
- COL4A6 | c.4327G>T p.G1443* | Nonsense Mutation (SNP) | VAF 21/29 reads (72%) | catalogued as COSV57881340; called by muse, mutect2, varscan2
- CSMD1 | c.9784T>A p.L3262I (on ENST00000520002; = p.L3261I on NM_033225.6) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV59397890; called by muse, mutect2, varscan2
- CTCF | c.873G>C p.E291D | Missense Mutation (SNP) | VAF 125/151 reads (83%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV50536174; called by muse, mutect2, varscan2
- DACH2 | c.1750+1G>T p.X584_splice | Splice Site (SNP) | VAF 40/54 reads (74%) | catalogued as rs768225591, COSV64189126; called by muse, mutect2, varscan2
- DCTN1 | c.1953C>G p.S651R | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62621711; called by muse, mutect2, varscan2
- DMD | c.5091G>C p.Q1697H | Missense Mutation (SNP) | VAF 190/312 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV63801114; called by muse, mutect2, varscan2
- DNAH17 | c.5444G>T p.G1815V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67762487; called by muse, mutect2, varscan2
- DNAI4 | c.354C>A p.D118E | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV64020246; called by muse, mutect2, varscan2
- DNMT3A | c.2209C>T p.L737F | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1340822377, COSV53082964; called by muse, mutect2, varscan2
- EPHA1 | c.2896C>T p.R966C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753594142, COSV51975038; called by muse, mutect2, varscan2
- EPS8 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV55537682; called by muse, mutect2, varscan2
- ERBB3 | c.3582T>A p.D1194E | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV57265246; called by muse, mutect2, varscan2
- F8 | c.6679G>C p.A2227P | Missense Mutation (SNP) | VAF 176/242 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM0911124, CM0911134, COSV57706915; called by muse, mutect2, varscan2
- FAP | c.1048-1G>C p.X350_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | catalogued as COSV51868679; called by muse, mutect2, varscan2
- FBXL7 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs774713699, COSV61654771; called by muse, mutect2, varscan2
- FKBP15 | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 112/277 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53040695; called by muse, mutect2, varscan2
- FOSL2 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV53106007; called by muse, mutect2, varscan2
- FRMPD3 | c.2002C>G p.R668G | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV52191020, COSV52198342; called by muse, mutect2, varscan2
- FUBP1 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV99627687; called by muse, mutect2
- GABRA3 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 82/144 reads (57%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.631); catalogued as rs202150301, COSV64805880; called by muse, mutect2, varscan2
- GNPAT | c.1528G>T p.V510F | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV64154579; called by muse, mutect2, varscan2
- GOLGA3 | c.2061G>C p.M687I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as COSV52646275; called by muse, mutect2
- GSDME | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100742221; called by muse, mutect2
- GYG1 | c.338A>T p.D113V | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV56051541; called by muse, mutect2, varscan2
- H2AC17 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs1343823503, COSV58154254; called by muse, mutect2, varscan2
- HEATR5B | c.5765C>G p.P1922R | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51849652, COSV51860424; called by muse, mutect2, varscan2
- HTT | c.5008C>T p.Q1670* | Nonsense Mutation (SNP) | VAF 24/634 reads (4%) | catalogued as COSV100750345; called by muse, mutect2
- IFT52 | c.955C>G p.P319A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV65976451; called by muse, mutect2, varscan2
- IGSF22 | c.1422G>C p.E474D | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV60039792; called by muse, mutect2, varscan2
- KBTBD3 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as COSV73241295, COSV73241666, COSV73241668; called by muse, mutect2, varscan2
- KCNH1 | c.1547T>C p.L516P (on ENST00000271751 / NM_172362.3; = p.L489P on NM_002238.4) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV55109133; called by muse, mutect2, varscan2
- KDM2B | c.3670G>T p.D1224Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65645982; called by muse, mutect2, varscan2
- KMT2C | c.10495C>G p.Q3499E | Missense Mutation (SNP) | VAF 481/852 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as rs745749081, COSV51514513; called by muse, mutect2, varscan2
- KRT4 | c.1457G>T p.S486I | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.118); catalogued as COSV53410489; called by muse, mutect2, varscan2
- LAMA3 | c.4736G>A p.R1579Q | Missense Mutation (SNP) | VAF 88/433 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs745925733, COSV52545118; called by muse, mutect2, varscan2
- LPCAT3 | c.1032G>C p.W344C | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54644182; called by muse, mutect2, varscan2
- LRRC30 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 27/116 reads (23%) | catalogued as COSV67302494; called by muse, mutect2, varscan2
- LRRC7 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs758484539, COSV60573805; called by muse, mutect2, varscan2
- LTN1 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV63735577; called by muse, mutect2, varscan2
- MME | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 69/632 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100852206; called by muse, mutect2, varscan2
- MTHFD1L | c.2739_2772del p.L914Gfs*14 | Frame Shift Del (DEL) | VAF 61/95 reads (64%) | catalogued as COSV66227980; called by mutect2, pindel, varscan2
- MUC4 | c.15208T>A p.Y5070N (on ENST00000463781 / NM_018406.7; = p.Y834N on NM_004532.6) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as COSV100203327; called by muse, varscan2
- MYH2 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV55450754; called by muse, mutect2, varscan2
- MYH4 | c.2779A>C p.T927P | Missense Mutation (SNP) | VAF 315/369 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV55125460, COSV55127999; called by muse, mutect2, varscan2
- MYOM1 | c.3439A>C p.N1147H | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV55302830; called by muse, mutect2, varscan2
- NALCN | c.4727T>C p.L1576P | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51971686; called by muse, mutect2, varscan2
- NAP1L1 | c.826A>C p.K276Q | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.612); catalogued as rs1483369924, COSV53876863; called by muse, mutect2, varscan2
- NCAM1 | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 84/116 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV57527115; called by muse, mutect2, varscan2
- NCOA6 | c.3967C>T p.R1323W | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs181662709; called by muse, mutect2, varscan2
- NEK10 | c.2623G>T p.D875Y | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV55366682; called by muse, mutect2, varscan2
- NIN | c.1665G>T p.Q555H | Missense Mutation (SNP) | VAF 6/180 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV99811369; called by muse, mutect2
- NSRP1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV55936010; called by muse, mutect2, varscan2
- NUP42 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); catalogued as rs76834116, COSV51731565; called by muse, mutect2, varscan2
- ODC1 | c.29A>G p.D10G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV52173808; called by muse, mutect2, varscan2
- OR2G6 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV58576150; called by muse, mutect2, varscan2
- OR4C12 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.285); catalogued as COSV58861406; called by muse, mutect2, varscan2
- OR5H15 | c.763C>A p.L255I | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV62949340; called by muse, mutect2, varscan2
- OR6A2 | c.644C>A p.P215Q | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60264745, COSV60266088; called by muse, mutect2, varscan2
- OTOF | c.4367C>T p.S1456F (on ENST00000272371 / NM_194248.3; = p.S689F on NM_004802.4) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55523712; called by muse, mutect2, varscan2
- OTOP3 | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV60915411; called by muse, mutect2, varscan2
- P2RY6 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.112); catalogued as COSV62938534; called by muse, mutect2, varscan2
- PAGE2 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV66596288; called by muse, mutect2, varscan2
- PALD1 | c.1359G>T p.W453C | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54979923, COSV99698352; called by muse, mutect2, varscan2
- PGLYRP4 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 80/335 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as rs201083169; called by muse, mutect2, varscan2
- PPIA | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); catalogued as COSV100587798; called by muse, mutect2
- RIMS4 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV65720998; called by muse, mutect2, varscan2
- ROS1 | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs957763915, COSV100877700, COSV63862695; called by muse, mutect2, varscan2
- SDC1 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV54341895; called by muse, mutect2, varscan2
- SELE | c.1181G>T p.C394F | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV60978231; called by muse, mutect2, varscan2
- SEZ6L | c.1642C>A p.Q548K | Missense Mutation (SNP) | VAF 137/166 reads (83%) | SIFT tolerated (0.53); PolyPhen benign (0.338); catalogued as COSV50698549; called by muse, mutect2, varscan2
- SHOC1 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1331367091, COSV59508042; called by muse, mutect2, varscan2
- SHROOM2 | c.2948G>C p.S983T | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as COSV66611387; called by muse, mutect2, varscan2
- SIVA1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV100328438; called by muse, mutect2, varscan2
- SLC25A51 | c.560A>T p.N187I | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54253924; called by muse, mutect2, varscan2
- SLC30A8 | c.988G>C p.V330L | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV69977365; called by muse, mutect2, varscan2
- SLC5A12 | c.1589G>A p.R530K | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68451872; called by muse, mutect2, varscan2
- SLC9B1 | c.1101G>C p.K367N | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV56476606; called by muse, mutect2, varscan2
- SRCAP | c.2867C>T p.S956F | Missense Mutation (SNP) | VAF 368/463 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52682763; called by muse, varscan2
- SUPT5H | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs370618161; called by muse, mutect2, varscan2
- SYK | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101002247; called by muse, mutect2, varscan2
- TENM1 | c.5903T>A p.V1968D | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948937; called by muse, mutect2
- TJP1 | c.2870A>T p.E957V | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.371); catalogued as COSV62047406; called by muse, mutect2, varscan2
- TMEM181 | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV65566267; called by muse, mutect2, varscan2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 44/69 reads (64%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- TRIM26 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 130/204 reads (64%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.488); catalogued as rs1483374501, COSV68962820; called by muse, mutect2, varscan2
- TSPAN9 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV50729349; called by muse, mutect2, varscan2
- TTF1 | c.719C>G p.S240W | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.303); catalogued as rs772587005, COSV57507904; called by muse, mutect2, varscan2
- TTK | c.641C>G p.S214* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as COSV57887512; called by muse, mutect2, varscan2
- TTN | c.13455G>T p.K4485N (on ENST00000591111; = p.K3558N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 185/202 reads (92%) | PolyPhen benign (0.083); catalogued as COSV60409906; called by muse, mutect2, varscan2
- TUBA3C | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV67140203; called by muse, mutect2, varscan2
- WFDC10B | c.122T>C p.I41T | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV57915090; called by muse, mutect2, varscan2
- XPNPEP1 | c.1546C>G p.R516G | Missense Mutation (SNP) | VAF 111/152 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59171595; called by muse, mutect2, varscan2
- XYLT1 | c.2545C>G p.P849A | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV54499066; called by muse, mutect2, varscan2
- ZDHHC19 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV56350265; called by muse, mutect2, varscan2
- ZNF182 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 129/227 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.13); catalogued as COSV59360098; called by muse, mutect2, varscan2
- ZNF649 | c.1406C>G p.A469G | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV100030701; called by muse, mutect2
- ASIC2 | c.1213_1223del p.L405Ffs*2 | Frame Shift Del (DEL) | VAF 89/141 reads (63%) | called by mutect2, pindel, varscan2
- DENND5A | c.1102_1120del p.L368Wfs*62 | Frame Shift Del (DEL) | VAF 45/306 reads (15%) | called by mutect2, pindel, varscan2
- DOCK4 | c.3216_3226del p.E1072Dfs*16 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | called by pindel, varscan2
- EEPD1 | c.931-21_935del p.X311_splice | Splice Site (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- GTF2H3 | c.914_*19del | Nonstop Mutation (DEL) | VAF 40/358 reads (11%) | called by mutect2, pindel
- HYDIN | c.14051A>T p.N4684I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); called by muse, mutect2
- MDS2 | n.732A>G | Splice Region (SNP) | VAF 41/127 reads (32%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.292-31_296del p.X98_splice | Splice Site (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- S100A13 | c.98_141del p.L33Pfs*10 | Frame Shift Del (DEL) | VAF 132/676 reads (20%) | called by mutect2, pindel
- SULF1 | c.1884_1889del p.C628_R630delins* | Nonsense Mutation (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- TPD52 | c.241_243del p.R81del (on ENST00000379097 / NM_001025252.3; = p.R41del on NM_005079.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 192/232 reads (83%) | called by pindel, varscan2
- TRAV1-1 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TSGA10IP | c.696_723del p.V233Rfs*103 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by mutect2, pindel, varscan2
- APOB | c.453T>C p.T151= | Silent (SNP) | VAF 52/242 reads (21%) | catalogued as COSV51957147; called by muse, mutect2, varscan2
- ATRNL1 | c.678T>C p.S226= | Silent (SNP) | VAF 73/251 reads (29%) | catalogued as rs782095260, COSV61819736; called by muse, mutect2, varscan2
- CAPN6 | c.615T>A p.T205= | Silent (SNP) | VAF 98/144 reads (68%) | catalogued as COSV60697653; called by muse, mutect2, varscan2
- CYP4F3 | c.792C>T p.H264= | Silent (SNP) | VAF 502/715 reads (70%) | catalogued as rs142562355; called by muse, mutect2, varscan2
- DMC1 | c.21G>A p.V7= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV53261426; called by muse, mutect2, varscan2
- DOCK4 | c.3234G>A p.Q1078= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs1413327966, COSV69855863; called by muse, varscan2
- DPPA2 | c.600G>A p.K200= | Silent (SNP) | VAF 49/167 reads (29%) | catalogued as rs760984281, COSV72118376; called by muse, mutect2, varscan2
- FNDC1 | c.4707G>A p.T1569= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as rs760868834, COSV51943539; called by muse, mutect2, varscan2
- FRAS1 | c.4917G>A p.Q1639= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV53656761; called by muse, mutect2, varscan2
- GPLD1 | c.858A>T p.A286= | Silent (SNP) | VAF 85/134 reads (63%) | catalogued as COSV57761614, COSV57761964; called by muse, mutect2, varscan2
- GPR149 | c.942C>A p.I314= | Silent (SNP) | VAF 41/255 reads (16%) | catalogued as COSV67670809; called by muse, mutect2, varscan2
- GRPR | c.705A>G p.K235= | Silent (SNP) | VAF 71/270 reads (26%) | catalogued as COSV66670413; called by muse, mutect2, varscan2
- HEPH | c.1575C>T p.A525= (on ENST00000343002; = p.A258= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as rs374611265, COSV57974010; called by muse, mutect2, varscan2
- HOXA6 | c.18G>A p.V6= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56075267; called by muse, mutect2, varscan2
- HTRA3 | c.1188T>G p.P396= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV56473867; called by muse, mutect2, varscan2
- IQGAP3 | c.709C>T p.L237= | Silent (SNP) | VAF 89/275 reads (32%) | catalogued as COSV63255245; called by muse, mutect2, varscan2
- ITPR1 | c.5688A>G p.P1896= (on ENST00000354582; = p.P1841= on NM_002222.7) | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as COSV57007892; called by muse, mutect2, varscan2
- KCNJ16 | c.138C>T p.Y46= | Silent (SNP) | VAF 53/363 reads (15%) | catalogued as COSV52257990; called by muse, mutect2, varscan2
- NUAK1 | c.1668C>G p.V556= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV54609448; called by muse, mutect2, varscan2
- OR4D5 | c.564C>A p.A188= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV100189704; called by muse, mutect2
- RUNX2 | c.507G>C p.R169= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100767092; called by muse, mutect2
- SAMSN1 | c.886C>T p.L296= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV104374909, COSV53478875; called by muse, mutect2, varscan2
- SDS | c.312C>G p.A104= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99980900; called by muse, mutect2
- SH3BP4 | c.1398G>A p.V466= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs781023270, COSV60647080; called by muse, mutect2, varscan2
- SLC16A14 | c.621G>T p.A207= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as rs765112155, COSV54617291, COSV54621945; called by muse, mutect2, varscan2
- SPATA7 | c.309T>G p.T103= | Silent (SNP) | VAF 75/292 reads (26%) | catalogued as COSV50421180; called by muse, mutect2, varscan2
- SPOP | c.966G>A p.V322= | Silent (SNP) | VAF 23/217 reads (11%) | catalogued as COSV100753137; called by muse, mutect2, varscan2
- STRC | c.741C>T p.L247= | Silent (SNP) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- SYNJ1 | c.1182C>G p.V394= | Silent (SNP) | VAF 77/202 reads (38%) | catalogued as COSV59158133; called by muse, mutect2, varscan2
- TACC2 | c.300G>A p.P100= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as rs373182521; called by muse, mutect2, varscan2
- TYRO3 | c.2319C>G p.P773= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV55487732; called by muse, mutect2, varscan2
- UHRF1 | c.1866G>A p.K622= (on ENST00000612630 / NM_001290050.1; = p.K635= on NM_013282.4) | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99503271; called by mutect2, varscan2
- USP19 | c.828C>T p.P276= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs765357414, COSV59730582; called by muse, mutect2, varscan2
- ZNF18 | c.651C>T p.L217= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs796336896, COSV100503022; called by muse, mutect2, varscan2
- CFAP65 | c.542+17T>A | Intron (SNP) | VAF 72/178 reads (40%) | catalogued as COSV55392276; called by muse, mutect2, varscan2
- DPP6 | c.627+20823T>A | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as COSV59650848; called by muse, mutect2, varscan2
- NR0B1 | c.1169-999_1169-991del | Intron (DEL) | VAF 8/55 reads (15%) | called by mutect2, varscan2
